Somatic mutation profile of tumor specimen ALCH-B1RP-TTP1-A (aliquot ALCH-B1RP-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1RP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.6 years (23,595 days).
Specimen ALCH-B1RP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3824d183-2afb-4a17-889b-2014707d03e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RP-NB1-A (Blood Derived Normal), aliquot ALCH-B1RP-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0414653-427c-4838-bd46-d46126c3a984

The open-access MAF lists 248 somatic variants for this specimen: 166 protein-altering or splice-affecting, 56 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 56, Nonsense Mutation 10, Intron 10, Splice Site 6, 3'UTR 5, 5'UTR 4, RNA 4, Frame Shift Del 3, Splice Region 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 27/232 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.5128C>T p.P1710S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as COSV61369508; called by muse, mutect2, varscan2
- ADARB1 | c.1622C>A p.T541K (on ENST00000360697 / NM_001346687.2; = p.T501K on NM_001112.4) | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV62344288; called by muse, mutect2, varscan2
- ALMS1 | c.748A>T p.S250C | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52509655; called by muse, mutect2
- ANK3 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 31/245 reads (13%) | catalogued as COSV99780601; called by muse, mutect2, varscan2
- ANKRD34B | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as COSV58613337; called by muse, mutect2, varscan2
- ARHGAP19 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.706); catalogued as rs1238236275, COSV57393953; called by muse, mutect2
- ATP2A3 | c.1811G>C p.R604P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988738; called by muse, mutect2, varscan2
- BSG | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1190178281, COSV61078082; called by muse, mutect2
- CALB1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 47/451 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV55368765; called by muse, mutect2, varscan2
- CARD8 | c.1309C>T p.L437F (on ENST00000651546 / NM_001184900.3; = p.L387F on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1336502823; called by muse, mutect2
- CCDC168 | c.7229G>A p.G2410E | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs542792016; called by muse, mutect2, varscan2
- CCDC39 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | catalogued as COSV99870497; called by muse, mutect2
- CCSER1 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 33/554 reads (6%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.025); catalogued as COSV104414393; called by muse, mutect2
- CD300A | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.831); catalogued as rs1300629659; called by muse, mutect2
- CSMD1 | c.2302G>C p.G768R (on ENST00000520002; = p.G767R on NM_033225.6) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59313228; called by muse, mutect2, varscan2
- CSMD3 | c.7680C>A p.F2560L (on ENST00000297405 / NM_001363185.1; = p.F2456L on NM_052900.3) | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52183174; called by muse, mutect2, varscan2
- DAXX | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs750390792; called by muse, mutect2
- DIDO1 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV56625478; called by muse, mutect2
- DNAH3 | c.11203G>A p.G3735R | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766826918, COSV54544813, COSV99771285; called by muse, mutect2, varscan2
- EIF2S3 | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.251); catalogued as COSV99451104; called by muse, mutect2, varscan2
- FAHD2B | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV55632085; called by muse, mutect2
- FAM83C | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV65582447; called by muse, mutect2, varscan2
- GOLGA6L2 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.882); catalogued as rs374438970, COSV100363189; called by muse, mutect2
- GRIA1 | c.84G>T p.G28= | Splice Region (SNP) | VAF 23/208 reads (11%) | catalogued as COSV53617088; called by muse, mutect2
- HAS1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs769387541, COSV55786715; called by mutect2, varscan2
- HEPN1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as rs775911527; called by muse, mutect2, varscan2
- HPRT1 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CD044270, CM044228; called by muse, mutect2, varscan2
- HTR6 | c.930C>G p.Y310* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs756701522, COSV53869724; called by muse, mutect2, varscan2
- KCNB2 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73048874; called by muse, mutect2
- KCNB2 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050758; called by muse, mutect2
- KMT2D | c.11035C>T p.Q3679* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as COSV56489054; called by muse, mutect2
- LAMA1 | c.2372G>A p.C791Y | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs138065938; called by muse, mutect2, varscan2
- LRP2 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55570305; called by muse, mutect2
- MEPCE | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV52769258; called by muse, mutect2, varscan2
- MYO18B | c.6235G>T p.D2079Y | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100125041; called by muse, mutect2, varscan2
- NLRP13 | c.2896G>C p.D966H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1026970984; called by muse, mutect2, varscan2
- OR51E1 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 43/615 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV67809530; called by muse, mutect2
- OTOG | c.7054G>A p.A2352T | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1217986162; called by muse, mutect2, varscan2
- PCDH17 | c.3280G>T p.D1094Y | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV64973557, COSV64976754; called by muse, mutect2
- PEG3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs766536993, COSV55639993, COSV99688363; called by muse, mutect2
- PTPRM | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs769632993; called by muse, mutect2
- RASA1 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs1297460918, COSV99169708; called by muse, mutect2
- RBM14 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59557570; called by muse, mutect2
- STXBP4 | c.1393A>C p.T465P | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100894837; called by muse, mutect2, varscan2
- TCFL5 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 53/504 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs375740957; called by muse, mutect2, varscan2
- TET1 | c.5638del p.H1880Tfs*38 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as COSV65385814; called by mutect2, pindel, varscan2
- TRPM1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 22/565 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754571296, COSV56632510; called by muse, mutect2
- TSPYL1 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV63994179; called by muse, mutect2
- TTN | c.82077C>A p.H27359Q (on ENST00000591111; = p.H19935Q on NM_003319.4) | Missense Mutation (SNP) | VAF 57/575 reads (10%) | PolyPhen possibly damaging (0.497); catalogued as COSV60444302; called by muse, mutect2, varscan2
- USH2A | c.8381T>C p.V2794A | Missense Mutation (SNP) | VAF 12/434 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV56367741; called by muse, mutect2
- WNK4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs200182836; ClinVar: benign; called by muse, mutect2
- WNT5B | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); catalogued as rs369464409; called by muse, mutect2, varscan2
- ACE | c.3482A>C p.K1161T | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ACIN1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2
- ACIN1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); called by muse, mutect2
- ACTL9 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN1 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2
- ALOX5 | c.241T>C p.W81R | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL5B | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AVEN | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BAP1 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163 | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- CD163 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CDH10 | c.2074C>A p.P692T | Missense Mutation (SNP) | VAF 32/784 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2
- CNKSR2 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- COL4A2 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.107); called by muse, mutect2
- COL9A1 | c.1999G>T p.G667C | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COLCA2 | c.307A>C p.I103L | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CRTC3 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.475); called by muse, mutect2
- DDO | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- DDRGK1 | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DEDD2 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX58 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- DMP1 | c.1254C>A p.S418R | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DNAH6 | c.2114A>C p.K705T | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2
- DSEL | c.2580G>T p.M860I | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- ELP4 | c.979G>T p.G327C (on ENST00000350638; = p.G326C on NM_019040.5) | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- EPB41L3 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ERG28 | c.343+2T>C p.X115_splice | Splice Site (SNP) | VAF 88/231 reads (38%) | called by muse, mutect2, varscan2
- EXO1 | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC3L2 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- F11 | c.1576+2T>G p.X526_splice | Splice Site (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- F5 | c.6508A>C p.K2170Q | Missense Mutation (SNP) | VAF 34/570 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); called by muse, mutect2
- FAM135B | c.3713A>T p.N1238I | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- FLI1 | c.1056C>A p.H352Q | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- FREM3 | c.6350A>G p.N2117S | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GJA10 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2
- GOLT1B | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 23/405 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- GPR183 | c.291G>C p.W97C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRID2 | c.2256T>A p.N752K | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.33); called by muse, mutect2
- GRK5 | c.150C>T p.D50= | Splice Region (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- H2BC10 | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); called by muse, mutect2
- HCFC1 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HDAC7 | c.2165C>A p.P722H (on ENST00000427332; = p.P761H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- HERC2 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.8609T>C p.I2870T | Missense Mutation (SNP) | VAF 24/767 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2
- IGKV1-12 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 38/453 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- IMMP1L | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- INTS1 | c.1157A>T p.D386V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- KANSL1L | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KATNIP | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- LDHAL6B | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LTF | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.131); called by muse, mutect2
- LTF | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- MDH1B | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2
- MPDZ | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- MRGPRX2 | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.464); called by muse, mutect2
- MTMR3 | c.3148C>T p.Q1050* | Nonsense Mutation (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- MUC4 | c.10687A>T p.T3563S | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MYCBP2 | c.13003G>C p.V4335L (on ENST00000357337; = p.V4373L on NM_015057.5) | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- MYO15A | c.9652G>A p.G3218R | Missense Mutation (SNP) | VAF 62/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO5B | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2
- NCF2 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 78/644 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NELL1 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPAP1 | c.1387C>A p.L463M | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.18); called by muse, mutect2
- NPHS1 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NRG1 | c.1775A>G p.Q592R (on ENST00000405005 / NM_013964.5; = p.Q597R on NM_013956.5) | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2
- OR2L3 | c.97A>C p.I33L | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR6C4 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR7A10 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- P4HTM | c.713del p.P238Lfs*7 | Frame Shift Del (DEL) | VAF 26/254 reads (10%) | called by mutect2, pindel, varscan2
- PAQR9 | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDH15 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA12 | c.2059G>T p.V687L | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDZRN4 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2
- PITX2 | c.757C>G p.L253V (on ENST00000354925 / NM_001204397.1; = p.L260V on NM_000325.6) | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PNPLA2 | c.1071del p.D358Tfs*9 | Frame Shift Del (DEL) | VAF 38/192 reads (20%) | called by mutect2, pindel, varscan2
- PPP1R7 | c.473A>C p.E158A | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTER | c.360T>G p.H120Q | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- PTPRQ | c.5226A>T p.K1742N (on ENST00000616559; = p.K1700N on NM_001145026.2) | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.197); called by muse, mutect2
- R3HDM4 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAPGEF6 | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- RTL3 | c.984C>A p.C328* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- SAA4 | c.91+1G>A p.X31_splice | Splice Site (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- SALL1 | c.2305C>A p.P769T | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDHD | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 29/639 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- SLC22A3 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SLC26A3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 64/535 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- SLIT2 | c.2034G>C p.W678C | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC1A | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.592); called by muse, mutect2
- SSB | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- STXBP4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 59/455 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUSD5 | c.1097G>C p.S366T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TECTA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/446 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.38); called by muse, mutect2
- TET1 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- TET2 | c.2590C>G p.H864D | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- TET2 | c.4368G>C p.M1456I | Missense Mutation (SNP) | VAF 22/447 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TMEM114 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, varscan2
- TPTE | c.812T>G p.L271R (on ENST00000618007 / NM_199261.4; = p.L253R on NM_199259.4) | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- TRDN | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.122); called by muse, mutect2
- TRIM68 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- TTLL7 | c.1067T>G p.F356C | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.88780A>G p.I29594V (on ENST00000591111; = p.I22170V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/209 reads (11%) | PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TTN | c.54290C>A p.P18097H (on ENST00000591111; = p.P10673H on NM_003319.4) | Missense Mutation (SNP) | VAF 36/774 reads (5%) | PolyPhen probably damaging (0.982); called by muse, mutect2
- TYW1B | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- USP40 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.055); called by muse, mutect2
- VWA5B2 | c.3647C>G p.A1216G | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR35 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- XPNPEP1 | c.247-2A>G p.X83_splice | Splice Site (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- ZNF317 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by mutect2, varscan2
- ZNF418 | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZNF423 | c.213T>G p.D71E (on ENST00000563137 / NM_001379286.1; = p.D63E on NM_015069.4) | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- ZNF679 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- ZNF681 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.078); called by muse, mutect2
- ZZZ3 | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- A1CF | c.1578T>A p.T526= (on ENST00000373993 / NM_138932.2; = p.T518= on NM_014576.4) | Silent (SNP) | VAF 34/290 reads (12%) | called by muse, varscan2
- ABCB1 | c.1839T>C p.D613= | Silent (SNP) | VAF 35/660 reads (5%) | catalogued as rs138926696; called by muse, mutect2
- AHNAK2 | c.6774C>T p.I2258= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as rs771297344; called by muse, mutect2, varscan2
- AKAP6 | c.1926A>G p.V642= | Silent (SNP) | VAF 40/321 reads (12%) | catalogued as rs1368615191; called by muse, mutect2, varscan2
- ALOX5 | c.534T>C p.F178= | Silent (SNP) | VAF 11/227 reads (5%) | catalogued as rs1170710428; called by muse, mutect2
- ANKK1 | c.1935G>T p.L645= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- ANTXR2 | c.732C>T p.F244= | Silent (SNP) | VAF 60/745 reads (8%) | called by muse, mutect2
- AQP6 | c.600C>T p.S200= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs556430357; called by muse, mutect2
- ATR | c.3366T>C p.Y1122= | Silent (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- CACUL1 | c.126C>T p.P42= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as rs1253058115; called by muse, mutect2
- CFHR3 | c.738G>A p.Q246= | Silent (SNP) | VAF 46/470 reads (10%) | catalogued as COSV100807479; called by muse, mutect2
- CNTN4 | c.2292T>C p.N764= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- COL22A1 | c.4251A>C p.G1417= | Silent (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- DENND2A | c.630C>T p.G210= | Silent (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- DUSP14 | c.351C>G p.R117= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- HCN1 | c.1485G>T p.V495= | Silent (SNP) | VAF 76/806 reads (9%) | catalogued as rs747328003, COSV100298034; called by muse, mutect2
- HMBS | c.954C>T p.I318= | Silent (SNP) | VAF 16/303 reads (5%) | catalogued as COSV53830378; called by muse, mutect2
- IL17RA | c.1575C>T p.L525= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as rs756587491; called by muse, mutect2, varscan2
- IL17REL | c.72G>C p.A24= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- IMPG1 | c.789A>T p.A263= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- MARCO | c.732A>T p.G244= | Silent (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- NBAS | c.897A>G p.T299= | Silent (SNP) | VAF 57/467 reads (12%) | called by muse, mutect2, varscan2
- NCOA6 | c.5682G>A p.V1894= | Silent (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- NEB | c.6144T>C p.P2048= | Silent (SNP) | VAF 35/612 reads (6%) | called by muse, mutect2
- NHS | c.18G>A p.R6= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- NKAIN3 | c.417C>T p.I139= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs748319917, COSV60661688; called by muse, mutect2
- ODF2L | c.771A>G p.T257= | Silent (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- OR11G2 | c.496C>A p.R166= | Silent (SNP) | VAF 30/291 reads (10%) | catalogued as COSV100639925, COSV62131721; called by muse, mutect2, varscan2
- OR2T10 | c.750C>A p.L250= | Silent (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- OR51F1 | c.429C>T p.T143= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- OVCH1 | c.1872C>A p.L624= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- PKHD1L1 | c.3801T>C p.N1267= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- POTEG | c.186C>T p.G62= | Silent (SNP) | VAF 41/1112 reads (4%) | called by muse, mutect2
- RGS20 | c.276A>T p.R92= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- RRP8 | c.879G>T p.L293= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2
- RYR1 | c.3867G>T p.R1289= | Silent (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- SERPINC1 | c.1254C>T p.T418= | Silent (SNP) | VAF 31/498 reads (6%) | catalogued as rs559277597, COSV62930039; called by muse, mutect2
- SFSWAP | c.1254C>T p.T418= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs1240401484; called by muse, mutect2, varscan2
- SHCBP1 | c.213C>T p.F71= | Silent (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- SLC44A5 | c.801T>A p.A267= | Silent (SNP) | VAF 53/459 reads (12%) | called by muse, mutect2, varscan2
- SMTN | c.702A>T p.P234= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- SPATA31E1 | c.2922G>A p.R974= | Silent (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- TCN1 | c.489C>A p.T163= | Silent (SNP) | VAF 30/620 reads (5%) | catalogued as rs185999138, COSV57252652; called by muse, mutect2
- THEM5 | c.286C>A p.R96= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- THSD4 | c.660A>G p.Q220= | Silent (SNP) | VAF 34/347 reads (10%) | called by muse, mutect2
- TONSL | c.309C>T p.H103= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- TOPORS | c.1698A>G p.T566= | Silent (SNP) | VAF 82/733 reads (11%) | catalogued as rs768575362; called by muse, mutect2, varscan2
- TSPYL6 | c.600C>A p.L200= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- UBE3C | c.2808C>T p.C936= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV100779811; called by muse, mutect2, varscan2
- USP15 | c.2505C>G p.L835= (on ENST00000280377 / NM_001351159.2; = p.L806= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- USP17L4 | c.1014T>C p.Y338= | Silent (SNP) | VAF 78/785 reads (10%) | catalogued as rs762260966; called by muse, mutect2
- WDCP | c.1119A>C p.S373= | Silent (SNP) | VAF 26/208 reads (13%) | called by muse, varscan2
- WWC3 | c.2880G>A p.E960= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- ZDHHC1 | c.1299G>A p.P433= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- ZP4 | c.1365T>C p.C455= | Silent (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.747C>T p.C249= (on ENST00000252463; = p.C304= on NM_032805.3) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV52966986, COSV52968809; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445608 C>A | 5'Flank (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- AL136439.1 | chr13:27665873 G>A | 3'Flank (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- C16orf91 | c.*106G>C | 3'UTR (SNP) | VAF 13/243 reads (5%) | catalogued as COSV59950492; called by muse, mutect2
- CDKL1 | c.172-3839A>G | Intron (SNP) | VAF 11/145 reads (8%) | catalogued as rs768074245; called by muse, mutect2
- CLC | c.*2C>A | 3'UTR (SNP) | VAF 23/233 reads (10%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2392A>G | 3'UTR (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- DTNBP1 | c.-58G>C | 5'UTR (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- EVI5L | c.1200+1004G>T | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- GPER1 | c.*738C>A | 3'UTR (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- KIAA0586 | c.4450+3792G>T | Intron (SNP) | VAF 18/513 reads (4%) | called by muse, mutect2
- LINC00587 | n.192C>A | RNA (SNP) | VAF 42/467 reads (9%) | called by muse, mutect2
- LINC00587 | n.193C>A | RNA (SNP) | VAF 40/466 reads (9%) | called by muse, mutect2
- LRRC37A6P | n.1483T>A | RNA (SNP) | VAF 18/343 reads (5%) | called by muse, mutect2
- LRRC55 | c.*6C>G | 3'UTR (SNP) | VAF 11/278 reads (4%) | catalogued as rs1317742405; called by muse, mutect2
- MFGE8 | c.73+1081C>G | Intron (SNP) | VAF 14/365 reads (4%) | called by muse, mutect2
- MIR124-2 | chr8:64377523 C>T | 5'Flank (SNP) | VAF 42/486 reads (9%) | called by muse, mutect2
- NFYC-AS1 | n.440C>A | RNA (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+609T>A | Intron (SNP) | VAF 20/504 reads (4%) | called by muse, mutect2
- PTK2B | c.811-38C>A | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- SLC10A3 | c.-57G>A | 5'UTR (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- SMPX | c.-107A>T | 5'UTR (SNP) | VAF 61/284 reads (21%) | called by muse, mutect2, varscan2
- TEX35 | c.342-102G>T | Intron (SNP) | VAF 16/256 reads (6%) | catalogued as COSV51105060; called by muse, mutect2
- TMEM132D | c.1444-15C>T | Intron (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- TNFRSF14 | c.-227C>G | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- USF2 | c.229-47C>A | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs913216206; called by muse, mutect2
- ZBBX | c.1880-6463T>C | Intron (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
